Somatic mutation profile of tumor specimen TARGET-10-PAPERN-09A (aliquot TARGET-10-PAPERN-09A-01D) from TARGET case TARGET-10-PAPERN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,384 days).
Specimen TARGET-10-PAPERN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 785298ca-c342-4cfc-b1a2-76c10f100bfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPERN-14A (Bone Marrow Normal), aliquot TARGET-10-PAPERN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2a94386-5505-4d67-8e5c-629df40383ab

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, 3'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10B | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 79/91 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100469689; called by muse, mutect2, varscan2
- NYNRIN | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs758876637, COSV66843565, COSV66844825; called by muse, mutect2
- OVGP1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 74/97 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs753225834, COSV63859076; called by muse, mutect2, varscan2
- IGHV3-53 | c.337_340del p.Y113Vfs*? | Frame Shift Del (DEL) | VAF 42/140 reads (30%) | called by mutect2, pindel
- ARHGAP28 | c.1389C>T p.F463= (on ENST00000383472 / NM_001366230.1; = p.F304= on NM_001010000.3) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV51645794; called by muse, mutect2, varscan2
- FIGNL2 | c.288C>A p.P96= | Silent (SNP) | VAF 70/76 reads (92%) | catalogued as rs757236575; called by muse, mutect2, varscan2
- PCDH11X | c.66C>T p.G22= | Silent (SNP) | VAF 135/145 reads (93%) | called by muse, mutect2, varscan2
- USP36 | c.3153G>A p.A1051= | Silent (SNP) | VAF 123/140 reads (88%) | catalogued as rs1402144789, COSV61753029; called by muse, mutect2, varscan2
- KRTAP19-6 | c.*59C>T | 3'UTR (SNP) | VAF 75/178 reads (42%) | catalogued as rs763913664, COSV61843797, COSV61843857; called by muse, mutect2, varscan2
- UBAP2L | c.*2G>T | 3'UTR (SNP) | VAF 42/55 reads (76%) | called by muse, mutect2, varscan2
